Somatic mutation profile of tumor specimen TCGA-B0-4698-01A (aliquot TCGA-B0-4698-01A-01D-1501-10) from TCGA case TCGA-B0-4698, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 75.1 years (27,417 days).
Specimen TCGA-B0-4698-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bb11345-8a4d-48f5-b4d0-c5d8259efcff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-4698-11A (Solid Tissue Normal), aliquot TCGA-B0-4698-11A-02D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8eb2a39f-abe0-4b9b-83ab-408d57cabb32

The open-access MAF lists 465 somatic variants for this specimen: 353 protein-altering or splice-affecting, 98 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 299, Silent 98, Nonsense Mutation 26, Splice Site 12, Intron 9, Frame Shift Del 6, RNA 4, Splice Region 4, Nonstop Mutation 3, 3'UTR 1, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.2301A>T p.L767F | Missense Mutation (SNP) | VAF 31/177 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705638, COSV66706950; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 237/406 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 35/69 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.14517C>A p.D4839E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.901); catalogued as rs764566470, COSV101291422; called by muse, mutect2, varscan2
- ABCA13 | c.14998G>T p.A5000S | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV101291234, COSV101291423; called by muse, mutect2, varscan2
- ABCC12 | c.3714A>T p.T1238= | Splice Region (SNP) | VAF 14/122 reads (11%) | catalogued as COSV100253121; called by muse, mutect2, varscan2
- AC098582.1 | c.184A>T p.T62S | Missense Mutation (SNP) | VAF 65/215 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as COSV99985922; called by muse, mutect2, varscan2
- ACADL | c.532G>T p.G178* | Nonsense Mutation (SNP) | VAF 104/408 reads (25%) | catalogued as COSV99285021; called by muse, varscan2
- ACVR2A | c.185C>A p.A62D | Missense Mutation (SNP) | VAF 72/546 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV99604980; called by muse, mutect2, varscan2
- ADAM15 | c.1027G>T p.A343S | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99665268; called by muse, varscan2
- ADAMTS16 | c.2065G>C p.D689H | Missense Mutation (SNP) | VAF 141/596 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs977466659, COSV99940766; called by muse, mutect2, varscan2
- ADD3 | c.1799C>T p.S600L | Missense Mutation (SNP) | VAF 101/339 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.253); catalogued as rs780415312, COSV99523672; called by muse, mutect2, varscan2
- ADGRF2 | c.1605G>T p.W535C (on ENST00000296862 / NM_001368115.2; = p.W467C on NM_153839.7) | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99731645; called by muse, mutect2, varscan2
- ADGRL3 | c.3037G>T p.A1013S (on ENST00000506720 / NM_001322402.2; = p.A945S on NM_015236.6) | Missense Mutation (SNP) | VAF 58/444 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV101547370; called by mutect2, varscan2
- AFDN | c.434C>A p.P145H | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as COSV60038918; called by muse, mutect2, varscan2
- AFM | c.670T>C p.C224R | Missense Mutation (SNP) | VAF 198/722 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99889131; called by muse, mutect2, varscan2
- AGGF1 | c.215A>T p.E72V | Missense Mutation (SNP) | VAF 84/324 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV100462163; called by muse, mutect2, varscan2
- AHNAK | c.4162C>G p.P1388A | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV57223431; called by muse, mutect2, varscan2
- AHNAK2 | c.13217C>T p.P4406L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1188360932, COSV60913648; called by muse, mutect2, varscan2
- AL592490.1 | c.2800G>T p.G934* | Nonsense Mutation (SNP) | VAF 51/285 reads (18%) | catalogued as COSV101308266; called by muse, mutect2, varscan2
- ALPK2 | c.956C>T p.T319I | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV64494723; called by muse, mutect2, varscan2
- AMY2B | c.789T>A p.F263L | Missense Mutation (SNP) | VAF 140/443 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.127); catalogued as COSV100796463; called by muse, varscan2
- AP4B1 | c.2069G>T p.G690V | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV99870645, COSV99871081; called by muse, mutect2, varscan2
- AP4B1 | c.2068G>T p.G690C | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99871083; called by muse, mutect2, varscan2
- APLNR | c.1043C>G p.S348W | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99951623; called by muse, varscan2
- ARHGEF28 | c.2551C>G p.Q851E | Missense Mutation (SNP) | VAF 64/404 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99709931; called by muse, mutect2, varscan2
- ARID3A | c.1462C>T p.Q488* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as COSV99708506; called by muse, varscan2
- ARSI | c.576C>G p.D192E | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100156091; called by muse, varscan2
- ASTN2 | c.1543G>T p.G515* (on ENST00000313400 / NM_001365069.1; = p.G464* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 27/114 reads (24%) | catalogued as COSV100529989, COSV57820735; called by muse, mutect2, varscan2
- ATP10B | c.1718C>A p.S573Y | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.454); catalogued as COSV100515640; called by muse, mutect2, varscan2
- ATP13A2 | c.2476A>T p.S826C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV100454386; called by muse, mutect2, varscan2
- BTNL8 | c.337G>T p.G113W | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99180567; called by muse, mutect2, varscan2
- C10orf53 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 72/211 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV65109524; called by muse, mutect2, varscan2
- CACNA1D | c.6165G>C p.Q2055H (on ENST00000350061 / NM_001128840.3; = p.Q2075H on NM_000720.4) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV99859713; called by muse, mutect2
- CACNA1I | c.2174G>A p.G725D | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100361318; called by muse, varscan2
- CAGE1 | c.598A>T p.M200L (on ENST00000512086; = p.M64L on NM_205864.3) | Missense Mutation (SNP) | VAF 95/242 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99700055; called by muse, mutect2, varscan2
- CASP14 | c.267C>A p.H89Q | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55665040, COSV99693121; called by muse, mutect2, varscan2
- CASP4 | c.722G>T p.R241L | Missense Mutation (SNP) | VAF 138/444 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.254); catalogued as COSV101274203, COSV67744159; called by muse, mutect2, varscan2
- CBX1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 132/481 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99848247; called by muse, mutect2, varscan2
- CBX4 | c.508G>T p.D170Y | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99490543; called by muse, mutect2, varscan2
- CCT8L2 | c.302G>T p.S101I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV100743046; called by muse, mutect2, varscan2
- CD300C | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV100423328; called by muse, mutect2, varscan2
- CDH12 | c.2276C>A p.T759K | Missense Mutation (SNP) | VAF 76/304 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.175); catalogued as COSV101203268; called by muse, varscan2
- CEACAM20 | c.992G>C p.S331T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.583); catalogued as COSV100387011; called by muse, mutect2, varscan2
- CFAP206 | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 77/419 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs561463743, COSV99739965; called by muse, mutect2, varscan2
- CFAP54 | c.6015-1G>T p.X2005_splice | Splice Site (SNP) | VAF 158/462 reads (34%) | catalogued as COSV100732878; called by mutect2, varscan2
- CLTA | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 175/808 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.257); catalogued as rs1330982564, COSV99643738; called by muse, mutect2, varscan2
- CNTN1 | c.383C>A p.A128E | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100751840; called by muse, mutect2
- COL26A1 | c.321C>A p.Y107* (on ENST00000313669 / NM_001278563.3; = p.Y105* on NM_133457.4) | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100561993; called by muse, mutect2, varscan2
- CPS1 | c.1531C>T p.Q511* | Nonsense Mutation (SNP) | VAF 63/222 reads (28%) | catalogued as COSV99243910; called by muse, mutect2, varscan2
- CPSF6 | c.1427G>A p.C476Y | Missense Mutation (SNP) | VAF 62/499 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99879653; called by muse, mutect2, varscan2
- CSMD1 | c.3005G>T p.G1002V (on ENST00000520002; = p.G1001V on NM_033225.6) | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59342723; called by muse, varscan2
- CSMD1 | c.3004G>T p.G1002W (on ENST00000520002; = p.G1001W on NM_033225.6) | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59293723, COSV59325241; called by muse, varscan2
- CSNK2A2 | c.1033G>T p.G345C | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.572); catalogued as COSV99345415; called by muse, mutect2, varscan2
- CTC1 | c.466C>T p.H156Y | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.836); catalogued as COSV100236720; called by muse, mutect2, varscan2
- CTNNA3 | c.575A>G p.Q192R | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs576347698, COSV100373780; called by muse, varscan2
- CYP2C19 | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 101/359 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374950950, COSV100990618; called by muse, mutect2, varscan2
- CYP7B1 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 50/254 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs750867598, COSV100042714; called by muse, mutect2, varscan2
- CYYR1 | c.74-1G>T p.X25_splice | Splice Site (SNP) | VAF 58/296 reads (20%) | catalogued as COSV100177507, COSV54835911; called by muse, mutect2, varscan2
- DCDC1 | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 69/296 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV100664091; called by muse, mutect2, varscan2
- DCSTAMP | c.467C>A p.T156N | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV52577662; called by muse, mutect2, varscan2
- DEFB115 | c.53T>A p.L18Q | Missense Mutation (SNP) | VAF 82/356 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101269327; called by muse, mutect2, varscan2
- DIAPH2 | c.1372C>A p.L458I | Missense Mutation (SNP) | VAF 93/198 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100234765; called by muse, mutect2, varscan2
- DMD | c.7404G>T p.E2468D | Missense Mutation (SNP) | VAF 95/180 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.283); catalogued as COSV100628940; called by muse, mutect2, varscan2
- DNAH10 | c.5438T>C p.V1813A (on ENST00000409039; = p.V1752A on NM_207437.3) | Missense Mutation (SNP) | VAF 79/187 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1409564069, COSV101292549; called by muse, mutect2, varscan2
- DSC3 | c.1682G>T p.G561V | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV64571694; called by muse, mutect2, varscan2
- DSCAM | c.2755G>C p.D919H | Missense Mutation (SNP) | VAF 67/477 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101261371, COSV68033183; called by muse, mutect2, varscan2
- EEPD1 | c.1577G>T p.G526V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54198747; called by muse, varscan2
- EGFLAM | c.1228C>A p.Q410K | Missense Mutation (SNP) | VAF 90/761 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV100380679, COSV100380903; called by muse, mutect2, varscan2
- EIF4E2 | c.737G>T p.*246Lext*43 | Nonstop Mutation (SNP) | VAF 12/99 reads (12%) | catalogued as COSV99299292; called by muse, mutect2
- EIF4G1 | c.3812C>G p.S1271* (on ENST00000346169 / NM_198241.3; = p.S1076* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100072232; called by muse, mutect2, varscan2
- ENOX2 | c.995-2A>T p.X332_splice (on ENST00000338144 / NM_001382520.1; = p.X303_splice on NM_006375.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 35/77 reads (45%) | catalogued as COSV100584506; called by muse, mutect2, varscan2
- ENPP2 | c.2506C>A p.L836M (on ENST00000075322 / NM_001040092.3; = p.L888M on NM_006209.5) | Missense Mutation (SNP) | VAF 72/368 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99309204; called by muse, mutect2, varscan2
- ENPP3 | c.2002G>T p.D668Y | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62956090; called by muse, mutect2, varscan2
- EP300 | c.1890C>G p.Y630* | Nonsense Mutation (SNP) | VAF 77/220 reads (35%) | catalogued as COSV99609574; called by muse, mutect2, varscan2
- EPHA5 | c.2146A>T p.K716* | Nonsense Mutation (SNP) | VAF 60/519 reads (12%) | catalogued as COSV56634634, COSV99900780; called by muse, mutect2, varscan2
- EPHA6 | c.1653T>G p.N551K | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.995); catalogued as COSV101065210; called by muse, mutect2, varscan2
- ESM1 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 40/384 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV101195708, COSV67318924; called by muse, varscan2
- F2RL1 | c.1046A>T p.H349L | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99688879; called by muse, mutect2
- FAM135B | c.3382C>A p.P1128T | Missense Mutation (SNP) | VAF 104/493 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.963); catalogued as COSV99426820; called by muse, mutect2, varscan2
- FAM135B | c.1694G>C p.R565T | Missense Mutation (SNP) | VAF 54/244 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs777160080, COSV52721993, COSV99426822; called by muse, mutect2, varscan2
- FAM153A | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.607); catalogued as COSV100647111; called by muse, mutect2, varscan2
- FAM153B | c.724G>C p.E242Q (on ENST00000253490; = p.E165Q on NM_001265615.1) | Missense Mutation (SNP) | VAF 87/633 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.506); catalogued as COSV99499104; called by muse, mutect2, varscan2
- FAM71B | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV100262268; called by muse, varscan2
- FAM71B | c.799G>T p.G267C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV100262269; called by muse, mutect2, varscan2
- FAT4 | c.2965G>C p.V989L | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV101272648; called by muse, mutect2, varscan2
- FBN2 | c.6511+1G>T p.X2171_splice | Splice Site (SNP) | VAF 71/253 reads (28%) | catalogued as rs746296572, COSV99330146; called by muse, mutect2, varscan2
- FBN2 | c.6511G>T p.D2171Y | Missense Mutation (SNP) | VAF 71/255 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99330149; called by muse, mutect2, varscan2
- FBXL13 | c.721G>C p.V241L | Missense Mutation (SNP) | VAF 42/264 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV100502023, COSV57538834; called by muse, mutect2, varscan2
- FBXO30 | c.2170A>G p.M724V | Missense Mutation (SNP) | VAF 38/242 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1207233273, COSV99395390; called by muse, mutect2, varscan2
- FNDC1 | c.350G>A p.S117N | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV99796545; called by muse, mutect2, varscan2
- FNDC4 | c.455G>C p.G152A | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.525); catalogued as COSV99254028; called by muse, mutect2
- FNDC4 | c.455-1G>A p.X152_splice | Splice Site (SNP) | VAF 14/68 reads (21%) | catalogued as COSV99254030; called by muse, mutect2
- GABRA1 | c.1130del p.P377Lfs*10 | Frame Shift Del (DEL) | VAF 20/183 reads (11%) | catalogued as COSV50108276, COSV50110447; called by mutect2, pindel, varscan2
- GABRA2 | c.1144C>A p.P382T | Missense Mutation (SNP) | VAF 57/248 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs758752896, COSV100734704, COSV62911680; called by muse, mutect2, varscan2
- GALNT5 | c.1804C>G p.L602V | Missense Mutation (SNP) | VAF 226/746 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99375518; called by muse, mutect2, varscan2
- GNS | c.1658A>T p.*553Lext*16 | Nonstop Mutation (SNP) | VAF 18/78 reads (23%) | catalogued as COSV99253989; called by muse, mutect2, varscan2
- GPR156 | c.1187C>A p.P396Q | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV100251661; called by muse, mutect2, varscan2
- GPR174 | c.204A>T p.Q68H | Missense Mutation (SNP) | VAF 81/167 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.105); catalogued as COSV99338346; called by muse, mutect2, varscan2
- GPRIN1 | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV99992105; called by muse, mutect2, varscan2
- GRIK2 | c.1185G>T p.K395N | Missense Mutation (SNP) | VAF 58/386 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.041); catalogued as COSV100023189; called by muse, mutect2, varscan2
- GRM5 | c.224C>A p.T75N | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100554088; called by mutect2, varscan2
- H2BC17 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV100377708, COSV58152797; called by muse, mutect2, varscan2
- HAVCR1 | c.419C>T p.T140I | Missense Mutation (SNP) | VAF 82/266 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.449); catalogued as rs1208324580, COSV59397718, COSV59400577; called by muse, mutect2, varscan2
- HECTD1 | c.1782G>C p.L594F | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); catalogued as COSV101237484, COSV67947070; called by muse, mutect2, varscan2
- HNRNPCL1 | c.257C>A p.A86E | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV100509148, COSV58611111; called by muse, mutect2, varscan2
- IGF2R | c.997G>T p.E333* | Nonsense Mutation (SNP) | VAF 11/82 reads (13%) | catalogued as COSV100808049; called by muse, mutect2, varscan2
- IL1RL2 | c.215G>T p.R72I | Missense Mutation (SNP) | VAF 39/319 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51818605; called by muse, mutect2, varscan2
- IL22RA1 | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.249); catalogued as COSV99583240; called by muse, mutect2, varscan2
- INPP5B | c.1828G>T p.G610W (on ENST00000373023; = p.G530W on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100886592, COSV65961926; called by muse, varscan2
- INSYN2A | c.1016C>A p.A339E | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.81); catalogued as COSV99732163; called by muse, mutect2
- ITGB5 | c.2329C>T p.P777S | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.026); catalogued as rs1224377391, COSV99951026; called by muse, mutect2, varscan2
- ITIH6 | c.2144C>A p.T715N | Missense Mutation (SNP) | VAF 83/186 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99513839; called by muse, mutect2, varscan2
- ITM2A | c.586C>G p.R196G | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV100964410; called by muse, mutect2, varscan2
- JAKMIP2 | c.844C>T p.R282* | Nonsense Mutation (SNP) | VAF 90/616 reads (15%) | catalogued as COSV54611876; called by muse, varscan2
- JUN | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.065); catalogued as COSV100973478; called by muse, varscan2
- KCNH8 | c.2758G>C p.E920Q | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV100110890; called by muse, mutect2, varscan2
- KCNT1 | c.3475G>T p.G1159* (on ENST00000488444; = p.G1140* on NM_001272003.2) | Nonsense Mutation (SNP) | VAF 39/176 reads (22%) | catalogued as COSV99706525; called by muse, mutect2, varscan2
- KIAA1109 | c.12975G>T p.Q4325H | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99172477; called by muse, mutect2, varscan2
- KIAA1549L | c.1229T>C p.L410P (on ENST00000321505; = p.L707P on NM_012194.3) | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV99684287; called by muse, mutect2, varscan2
- KIF17 | c.1115G>T p.S372I | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV99929618; called by muse, mutect2
- KLHL14 | c.1712G>C p.S571T | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs547115353, COSV100839298; called by muse, mutect2, varscan2
- KRT33A | c.750+1G>T p.X250_splice | Splice Site (SNP) | VAF 11/69 reads (16%) | catalogued as rs759631719, COSV99144994; called by muse, mutect2, varscan2
- KRT4 | c.741C>T p.D247= | Splice Region (SNP) | VAF 15/71 reads (21%) | catalogued as rs369593094; called by muse, mutect2
- KRT73 | c.1571C>G p.S524C | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.246); catalogued as rs769635101, COSV99988800, COSV99988951; called by muse, mutect2, varscan2
- KRTAP10-9 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs1359595548, COSV100555228; called by muse, mutect2, varscan2
- LAMA4 | c.4927G>A p.G1643S (on ENST00000230538 / NM_001105206.3; = p.G1636S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs782400784, COSV100039250; called by muse, mutect2, varscan2
- LAMB1 | c.2267G>T p.R756I | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV99741546; called by muse, mutect2, varscan2
- LANCL3 | c.1033G>A p.G345S | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1556434366, COSV101065738; called by muse, mutect2, varscan2
- LARP4 | c.498G>T p.L166F | Missense Mutation (SNP) | VAF 76/444 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53326987; called by muse, varscan2
- LARP4B | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 46/302 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs555331681, COSV100295610; called by muse, varscan2
- LBP | c.649C>G p.P217A | Missense Mutation (SNP) | VAF 86/394 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV99461226; called by muse, mutect2, varscan2
- LILRA1 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV52184911, COSV99252093; called by muse, varscan2
- LPA | c.134C>A p.T45K | Missense Mutation (SNP) | VAF 37/236 reads (16%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.985); catalogued as COSV100307891; called by muse, mutect2, varscan2
- LPGAT1 | c.453G>T p.Q151H | Missense Mutation (SNP) | VAF 125/356 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100878220; called by muse, mutect2, varscan2
- LPXN | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV101223116; called by muse, mutect2, varscan2
- LRFN5 | c.2142+1G>T p.X714_splice | Splice Site (SNP) | VAF 100/454 reads (22%) | catalogued as COSV99985183; called by muse, varscan2
- LRP1B | c.4279C>A p.P1427T | Missense Mutation (SNP) | VAF 44/332 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV101259958, COSV67184228; called by muse, varscan2
- LRP1B | c.1504C>A p.R502S | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101259959; called by muse, mutect2, varscan2
- LRP8 | c.2780C>T p.P927L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.028); catalogued as rs200406029, COSV100036850; called by muse, mutect2, varscan2
- LRRC4C | c.1210G>T p.A404S | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99539406; called by muse, mutect2, varscan2
- LRRC7 | c.1007T>C p.L336S (on ENST00000651989 / NM_001370785.2; = p.L303S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99229243; called by muse, varscan2
- LRRTM3 | c.58C>A p.P20T | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.114); catalogued as rs1374123457, COSV100791887; called by muse, mutect2, varscan2
- LTBP2 | c.1190T>A p.I397N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100000857; called by muse, varscan2
- MAGEB6 | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT tolerated (0.87); PolyPhen benign (0.111); catalogued as COSV100983837, COSV66872792; called by muse, mutect2, varscan2
- MAP3K4 | c.2332T>C p.W778R | Missense Mutation (SNP) | VAF 92/555 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.91); catalogued as rs1017699440, COSV100815640; called by muse, mutect2
- MATN2 | c.2293G>T p.V765L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99646988; called by muse, mutect2, varscan2
- MDGA1 | c.2324G>C p.R775P | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99777286, COSV99777507; called by muse, mutect2, varscan2
- MIA2 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV99698107; called by muse, mutect2, varscan2
- MMP2 | c.1268C>A p.P423H | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99528200; called by muse, mutect2, varscan2
- MMP2 | c.1942G>T p.V648L | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.039); catalogued as COSV50895600, COSV99528206; called by muse, mutect2, varscan2
- MMRN1 | c.6G>T p.K2N | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV99306930, COSV99307675; called by muse, mutect2, varscan2
- MORC3 | c.2660G>C p.G887A | Missense Mutation (SNP) | VAF 67/358 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.152); catalogued as COSV101265026; called by muse, mutect2, varscan2
- MSH4 | c.2619+1G>T p.X873_splice | Splice Site (SNP) | VAF 32/188 reads (17%) | catalogued as COSV99592385; called by muse, mutect2, varscan2
- MUC16 | c.26969C>T p.T8990I | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.737); catalogued as rs371401091, COSV101201200; called by muse, mutect2, varscan2
- MUC16 | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV101201204; called by muse, mutect2, varscan2
- MUC17 | c.3104C>A p.S1035* | Nonsense Mutation (SNP) | VAF 26/122 reads (21%) | catalogued as COSV100074789; called by muse, mutect2, varscan2
- MUC17 | c.11321C>A p.P3774H | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs1562819060, COSV100074792; called by muse, mutect2, varscan2
- MYBL2 | c.1684G>T p.D562Y | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV53829439, COSV99406668; called by muse, mutect2, varscan2
- MYBPC3 | c.854A>C p.D285A | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV99920907; called by muse, mutect2, varscan2
- MYCBP2 | c.11978A>T p.Q3993L (on ENST00000357337; = p.Q4031L on NM_015057.5) | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.204); catalogued as COSV100631541; called by muse, mutect2, varscan2
- MYH13 | c.2725T>G p.C909G | Missense Mutation (SNP) | VAF 62/458 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1438063017, COSV99355172; called by muse, varscan2
- MYH2 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 132/325 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55438893, COSV99820797; called by muse, varscan2
- MYO16 | c.818T>G p.L273R | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV51787442, COSV51819118; called by muse, varscan2
- MYO18B | c.6829A>T p.T2277S | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.019); catalogued as COSV100124915; called by muse, mutect2, varscan2
- MYOM2 | c.3042C>T p.P1014= | Splice Region (SNP) | VAF 78/320 reads (24%) | catalogued as rs1237019553, COSV50767523; called by muse, mutect2, varscan2
- NCAM2 | c.826G>A p.G276S | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.183); catalogued as rs909572080, COSV99521945, COSV99524877; called by muse, mutect2, varscan2
- NEB | c.3502T>A p.Y1168N | Missense Mutation (SNP) | VAF 73/257 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99427020; called by muse, mutect2, varscan2
- NETO1 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100199504; called by muse, mutect2, varscan2
- NEUROD6 | c.431G>A p.W144* | Nonsense Mutation (SNP) | VAF 32/163 reads (20%) | catalogued as COSV99774166; called by muse, varscan2
- NF2 | c.241-2A>G p.X81_splice | Splice Site (SNP) | VAF 108/296 reads (36%) | catalogued as CS045481, CS050109, CS077993, COSV58523854, COSV58530980; called by muse, mutect2, varscan2
- NLRP11 | c.2403C>A p.F801L | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100789797; called by mutect2, varscan2
- NOL8 | c.287C>A p.A96D | Missense Mutation (SNP) | VAF 93/819 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100694669, COSV62636299; called by muse, mutect2, varscan2
- NPAP1 | c.2206A>T p.S736C | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.837); catalogued as COSV100276026; called by muse, mutect2, varscan2
- NPAS3 | c.370A>C p.N124H (on ENST00000356141 / NM_001164749.2; = p.N94H on NM_022123.3) | Missense Mutation (SNP) | VAF 44/289 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.898); catalogued as COSV100389539, COSV58091667; called by muse, mutect2, varscan2
- NPAS4 | c.749G>T p.W250L | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100215204; called by muse, mutect2, varscan2
- NR3C2 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.062); catalogued as COSV100678871, COSV100679664; called by muse, mutect2, varscan2
- NRG1 | c.595G>T p.V199L | Missense Mutation (SNP) | VAF 78/322 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs762642443, COSV99829297; called by muse, mutect2, varscan2
- NRIP1 | c.712G>C p.A238P | Missense Mutation (SNP) | VAF 46/263 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); catalogued as COSV100013026; called by muse, mutect2, varscan2
- NTM | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100869362; called by muse, varscan2
- OPRM1 | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 57/282 reads (20%) | catalogued as COSV100386152, COSV57821500, COSV57834430; called by muse, mutect2, varscan2
- OR10G7 | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 48/290 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57868109; called by muse, mutect2, varscan2
- OR11G2 | c.961C>A p.P321T | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100640035, COSV62132965; called by muse, mutect2, varscan2
- OR13C4 | c.59A>T p.Y20F | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV99470280; called by muse, mutect2, varscan2
- OR1C1 | c.725G>T p.S242I | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV101376270, COSV68715401; called by muse, mutect2, varscan2
- OR2C3 | c.65C>A p.P22H | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV100825773; called by muse, mutect2, varscan2
- OR2L8 | c.416T>A p.V139E | Missense Mutation (SNP) | VAF 147/495 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV61727081; called by muse, mutect2, varscan2
- OR52J3 | c.119del p.A40Vfs*10 | Frame Shift Del (DEL) | VAF 21/169 reads (12%) | catalogued as COSV66747609; called by mutect2, pindel, varscan2
- OR52K2 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV100355828; called by muse, mutect2, varscan2
- OR5M11 | c.892C>A p.Q298K | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs771264596, COSV101602062; called by muse, mutect2, varscan2
- OR5T1 | c.623A>T p.Q208L | Missense Mutation (SNP) | VAF 99/383 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as COSV100479192; called by muse, mutect2, varscan2
- OR5W2 | c.784C>G p.P262A | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV100747734, COSV60615589; called by muse, mutect2, varscan2
- OR8K5 | c.774G>T p.M258I | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.749); catalogued as COSV100537312; called by muse, mutect2, varscan2
- OTOGL | c.1952C>T p.S651F (on ENST00000547103; = p.S642F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/250 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV101509485; called by muse, mutect2, varscan2
- OTOGL | c.2794T>C p.C932R (on ENST00000547103; = p.C923R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/490 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756540915, COSV101509486; called by muse, mutect2
- OTX1 | c.967G>T p.G323C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.258); catalogued as COSV99246498; called by muse, varscan2
- OTX1 | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV56994871, COSV99246499; called by muse, varscan2
- PADI6 | c.1423T>A p.W475R | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100640004; called by muse, mutect2, varscan2
- PANK2 | c.1413-2A>G p.X471_splice (on ENST00000316562 / NM_153638.3; = p.X180_splice on NM_024960.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 40/160 reads (25%) | catalogued as COSV100262474; called by muse, mutect2, varscan2
- PAPOLG | c.1682A>T p.N561I | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV99475063; called by muse, mutect2
- PAPOLG | c.1684A>T p.S562C | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99475065; called by muse, mutect2
- PAX8 | c.80C>A p.P27Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99640013; called by muse, mutect2, varscan2
- PCDH1 | c.1708C>G p.L570V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99746839; called by muse, mutect2, varscan2
- PCDHA3 | c.1313C>A p.T438K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV100793691, COSV63542619; called by muse, varscan2
- PCDHA6 | c.620C>G p.A207G | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.244); catalogued as COSV100972502; called by muse, mutect2, varscan2
- PDCD11 | c.643C>A p.L215M | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100874406, COSV63935619; called by muse, mutect2, varscan2
- PDE2A | c.2150C>T p.A717V | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as rs1297336200, COSV100558325; called by muse, mutect2, varscan2
- PEG3 | c.973A>T p.S325C | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV99690150; called by muse, mutect2, varscan2
- PICALM | c.766-1G>T p.X256_splice | Splice Site (SNP) | VAF 29/194 reads (15%) | catalogued as COSV100708174; called by muse, mutect2, varscan2
- PKHD1L1 | c.5152G>T p.A1718S | Missense Mutation (SNP) | VAF 59/258 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV101006717, COSV101006768; called by muse, mutect2, varscan2
- PLA1A | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 38/335 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as COSV99846034; called by muse, mutect2, varscan2
- PLA2G10 | c.453C>G p.F151L | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.023); catalogued as COSV99902409; called by muse, mutect2, varscan2
- PLCXD1 | c.317G>T p.R106L | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV101087993; called by muse, mutect2, varscan2
- PLG | c.1589A>G p.Y530C | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99805033; called by muse, mutect2, varscan2
- PLPBP | c.702A>T p.E234D | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV100065811; called by muse, mutect2, varscan2
- PLPPR5 | c.612G>T p.M204I | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV54174199, COSV99587802; called by muse, mutect2, varscan2
- PLXDC1 | c.645C>A p.D215E | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as COSV100195763; called by muse, mutect2, varscan2
- POLQ | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV51756190; called by muse, mutect2, varscan2
- POSTN | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 57/377 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101123451; called by muse, mutect2, varscan2
- PPARGC1B | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV100495087; called by muse, mutect2, varscan2
- PPFIA1 | c.2323G>T p.G775C | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV99557952; called by muse, mutect2, varscan2
- PPM1A | c.626G>A p.G209D | Missense Mutation (SNP) | VAF 71/245 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.242); catalogued as COSV100349399; called by muse, mutect2, varscan2
- PPM1K | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs371441971, COSV99901146; called by muse, mutect2, varscan2
- PRDM7 | c.565C>G p.H189D | Missense Mutation (SNP) | VAF 34/228 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.115); catalogued as COSV100371116, COSV100371329; called by muse, varscan2
- PRDM9 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as COSV57014897, COSV99691080; called by muse, mutect2, varscan2
- PRKCG | c.1373C>A p.A458E | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.33); catalogued as COSV54726488, COSV99668833; called by muse, mutect2, varscan2
- PRSS38 | c.401G>T p.R134M | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100816554; called by muse, mutect2, varscan2
- PSG4 | c.4G>T p.G2W | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54935691; called by muse, mutect2
- PTCD3 | c.949C>A p.L317M | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.646); catalogued as COSV99606584; called by muse, mutect2, varscan2
- PTGER2 | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs1337144622, COSV99817705; called by muse, mutect2, varscan2
- PTH1R | c.1373T>C p.I458T | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as CM139324, CM991084, COSV100481148; called by muse, mutect2, varscan2
- PTOV1 | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV99681984; called by muse, mutect2, varscan2
- PTPRB | c.464C>A p.A155E | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.494); catalogued as COSV100547863; called by muse, mutect2, varscan2
- PTPRZ1 | c.1516C>A p.P506T | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs182147530, COSV101100720; called by muse, mutect2, varscan2
- PWWP3B | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV61798457; called by muse, mutect2, varscan2
- RAB9A | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99689764; called by muse, mutect2, varscan2
- RAD21 | c.1697G>T p.G566V | Missense Mutation (SNP) | VAF 157/563 reads (28%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.996); catalogued as COSV99815562; called by muse, mutect2, varscan2
- RAD21 | c.1696G>T p.G566C | Missense Mutation (SNP) | VAF 157/566 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV99815563; called by muse, mutect2, varscan2
- RAD23A | c.685G>C p.E229Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.096); catalogued as COSV100331019, COSV57135475; called by muse, mutect2, varscan2
- RAD50 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 132/444 reads (30%) | catalogued as COSV54751199, COSV99528402; called by muse, mutect2, varscan2
- RAD51AP2 | c.1637G>T p.G546V | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV101208403; called by muse, mutect2, varscan2
- RAE1 | c.943G>T p.D315Y | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as rs933510491, COSV100982473; called by muse, mutect2, varscan2
- RALGAPB | c.3647C>G p.S1216C | Missense Mutation (SNP) | VAF 107/478 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV99485681; called by muse, mutect2, varscan2
- RAN | c.364A>T p.N122Y | Missense Mutation (SNP) | VAF 29/274 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99619850; called by muse, mutect2, varscan2
- RAPGEF6 | c.2865-2A>T p.X955_splice | Splice Site (SNP) | VAF 36/184 reads (20%) | catalogued as COSV99727651; called by muse, mutect2
- RBBP6 | c.3538C>G p.P1180A | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.232); catalogued as COSV100154893; called by muse, mutect2, varscan2
- RBFA | c.149C>G p.S50W | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100080308; called by muse, mutect2, varscan2
- RCSD1 | c.422C>A p.P141H | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100827762; called by muse, mutect2, varscan2
- RCSD1 | c.563G>T p.R188M | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.818); catalogued as rs757141452, COSV100827764; called by muse, mutect2, varscan2
- RCSD1 | c.564G>T p.R188S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.196); catalogued as COSV100827766; called by muse, mutect2, varscan2
- RELN | c.6608T>A p.L2203H | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100634661; called by muse, mutect2, varscan2
- RESF1 | c.3748G>T p.E1250* | Nonsense Mutation (SNP) | VAF 105/174 reads (60%) | catalogued as COSV100440551; called by muse, mutect2, varscan2
- RIMS4 | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as COSV65720219; called by muse, mutect2, varscan2
- RIMS4 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as COSV100865207; called by muse, mutect2, varscan2
- RNF17 | c.3787G>T p.D1263Y | Missense Mutation (SNP) | VAF 41/317 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55054158; called by muse, mutect2, varscan2
- ROBO1 | c.1276T>C p.Y426H | Missense Mutation (SNP) | VAF 36/266 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1221930779, COSV101459187; called by muse, mutect2, varscan2
- RTTN | c.949G>T p.G317W | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99733633; called by muse, mutect2, varscan2
- RYR1 | c.8067G>A p.K2689= | Splice Region (SNP) | VAF 16/78 reads (21%) | catalogued as CS105863, COSV62094804; called by muse, mutect2, varscan2
- SAGE1 | c.755A>T p.N252I | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100187787; called by muse, mutect2, varscan2
- SALL1 | c.2304C>A p.C768* | Nonsense Mutation (SNP) | VAF 10/128 reads (8%) | catalogued as COSV51754480, COSV51765710; called by muse, mutect2
- SCUBE1 | c.344G>C p.C115S | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99298571; called by muse, mutect2, varscan2
- SELPLG | c.894G>T p.M298I | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV99947614; called by muse, mutect2, varscan2
- SERPINB11 | c.248T>C p.I83T | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.691); catalogued as rs566928200, COSV101236313; called by muse, mutect2, varscan2
- SERPINB11 | c.503G>A p.S168N | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV101236207; called by muse, mutect2, varscan2
- SEZ6L | c.2235C>A p.C745* | Nonsense Mutation (SNP) | VAF 68/148 reads (46%) | catalogued as COSV99962778; called by muse, mutect2, varscan2
- SGK2 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV100414811; called by muse, mutect2, varscan2
- SHANK2 | c.5146G>C p.E1716Q | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV53585925, COSV99571432; called by muse, mutect2, varscan2
- SIPA1L1 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100665973; called by muse, mutect2, varscan2
- SIPA1L1 | c.957A>T p.E319D | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV100665976; called by muse, mutect2, varscan2
- SLC15A2 | c.1192G>C p.E398Q | Missense Mutation (SNP) | VAF 32/296 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.359); catalogued as COSV99815116; called by muse, mutect2
- SLC17A8 | c.703A>T p.M235L | Missense Mutation (SNP) | VAF 350/777 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.267); catalogued as COSV100035778; called by muse, mutect2, varscan2
- SLC44A5 | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 54/281 reads (19%) | catalogued as COSV100902474; called by muse, varscan2
- SLC6A3 | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99548756; called by muse, mutect2, varscan2
- SLC8A1 | c.1120G>T p.G374* | Nonsense Mutation (SNP) | VAF 32/220 reads (15%) | catalogued as COSV100246867; called by muse, mutect2, varscan2
- SLCO2B1 | c.703A>G p.M235V | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.087); catalogued as rs745520331, COSV99215089; called by mutect2, varscan2
- SMAD1 | c.1021G>T p.G341W | Missense Mutation (SNP) | VAF 92/317 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100129895; called by muse, mutect2, varscan2
- SMG1 | c.6542A>G p.N2181S | Missense Mutation (SNP) | VAF 104/411 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV101246711; called by muse, mutect2, varscan2
- SNX10 | c.249C>A p.F83L | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV100640130; called by muse, mutect2, varscan2
- SPAG16 | c.1241G>C p.G414A | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100535102; called by muse, mutect2, varscan2
- SPANXN4 | c.293A>G p.Q98R | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs758788318, COSV100981013; called by muse, mutect2
- SPATA4 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99709085; called by muse, mutect2, varscan2
- SPCS2 | c.435G>T p.R145S | Missense Mutation (SNP) | VAF 75/416 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV99734538; called by muse, mutect2, varscan2
- SPOP | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.881); catalogued as COSV100753557; called by muse, mutect2, varscan2
- SPTBN5 | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100312083; called by muse, mutect2, varscan2
- STK11IP | c.1642G>A p.G548R | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as rs1165095094, COSV99823279; called by muse, mutect2, varscan2
- TALDO1 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100032841; called by muse, mutect2, varscan2
- TBC1D31 | c.374A>C p.H125P | Missense Mutation (SNP) | VAF 117/422 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99783140; called by muse, mutect2, varscan2
- TBX18 | c.1220G>T p.S407I | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.572); catalogued as COSV100858565; called by muse, varscan2
- TCEAL8 | c.226A>G p.I76V | Missense Mutation (SNP) | VAF 174/330 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.096); catalogued as COSV100749838; called by muse, mutect2, varscan2
- TDRD3 | c.1591C>G p.P531A | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99541076; called by muse, mutect2, varscan2
- THAP5 | c.1089A>C p.E363D (on ENST00000415914 / NM_001130475.3; = p.E321D on NM_182529.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/283 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100542887; called by muse, mutect2, varscan2
- TNFSF11 | c.748C>A p.P250T | Missense Mutation (SNP) | VAF 44/258 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as COSV99520676; called by muse, mutect2, varscan2
- TOP2B | c.2855G>C p.W952S (on ENST00000264331 / NM_001330700.2; = p.W947S on NM_001068.3) | Missense Mutation (SNP) | VAF 56/449 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99980207; called by muse, mutect2
- TPBG | c.1175G>T p.C392F | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1413458612, COSV100869807; called by muse, mutect2, varscan2
- TRAF3IP2 | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100389863; called by muse, mutect2, varscan2
- TRIP11 | c.3524C>G p.A1175G | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99971087; called by muse, mutect2, varscan2
- TRPV5 | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 38/306 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99520936; called by muse, varscan2
- TSHZ3 | c.1051G>T p.A351S | Missense Mutation (SNP) | VAF 138/509 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV53667711; called by muse, mutect2, varscan2
- TTN | c.68621G>C p.R22874T (on ENST00000591111; = p.R15450T on NM_003319.4) | Missense Mutation (SNP) | VAF 14/120 reads (12%) | PolyPhen benign (0.439); catalogued as rs1470812776, COSV100626573; called by muse, mutect2, varscan2
- TTN | c.37711A>G p.K12571E (on ENST00000591111; = p.K5147E on NM_003319.4) | Missense Mutation (SNP) | VAF 116/408 reads (28%) | PolyPhen benign (0.247); catalogued as COSV100626574; called by muse, mutect2, varscan2
- TXNDC12 | c.494A>G p.K165R | Missense Mutation (SNP) | VAF 63/364 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV100860922; called by muse, varscan2
- UBAC2 | c.575G>T p.C192F (on ENST00000403766 / NM_001144072.2; = p.C157F on NM_177967.4) | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100854377; called by muse, mutect2, varscan2
- UBE3C | c.135G>T p.R45S | Missense Mutation (SNP) | VAF 60/388 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100780068; called by muse, mutect2, varscan2
- UPK1B | c.738G>A p.W246* | Nonsense Mutation (SNP) | VAF 113/843 reads (13%) | catalogued as COSV99953787; called by muse, mutect2, varscan2
- URGCP | c.2689G>T p.E897* (on ENST00000453200 / NM_001077663.3; = p.E888* on NM_017920.4) | Nonsense Mutation (SNP) | VAF 25/113 reads (22%) | catalogued as COSV56252047; called by muse, mutect2, varscan2
- VEZT | c.769G>T p.G257C | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99704241; called by muse, mutect2, varscan2
- VPS13C | c.10826A>G p.Y3609C (on ENST00000644861 / NM_020821.3; = p.Y3566C on NM_017684.5) | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99829900; called by muse, mutect2, varscan2
- VPS13C | c.7336G>T p.G2446C (on ENST00000644861 / NM_020821.3; = p.G2403C on NM_017684.5) | Missense Mutation (SNP) | VAF 97/235 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV99829903; called by muse, mutect2, varscan2
- WDR49 | c.1079G>A p.R360H (on ENST00000308378 / NM_001366158.1; = p.R701H on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs199677479; called by muse, mutect2, varscan2
- WDR93 | c.397A>T p.K133* | Nonsense Mutation (SNP) | VAF 133/360 reads (37%) | catalogued as COSV99175774; called by muse, mutect2, varscan2
- XIRP2 | c.8975G>T p.R2992I (on ENST00000628543; = p.R3167I on NM_152381.6) | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV99746574; called by muse, mutect2, varscan2
- XPOT | c.1061A>G p.Y354C | Missense Mutation (SNP) | VAF 47/257 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100225716; called by muse, mutect2, varscan2
- YEATS2 | c.694C>A p.H232N | Missense Mutation (SNP) | VAF 36/307 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100528233; called by muse, mutect2, varscan2
- ZFHX4 | c.4114G>A p.D1372N | Missense Mutation (SNP) | VAF 35/331 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.206); catalogued as rs758151619, COSV50795888, COSV99266657; called by muse, mutect2, varscan2
- ZNF143 | c.679G>T p.A227S | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as COSV100217991; called by muse, mutect2, varscan2
- ZNF143 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 34/292 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100217992; called by muse, varscan2
- ZNF182 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 79/146 reads (54%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as COSV59357998; called by muse, mutect2, varscan2
- ZNF221 | c.890T>C p.L297P | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99240901; called by muse, mutect2, varscan2
- ZNF222 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 66/243 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV51828162; called by muse, mutect2, varscan2
- ZNF285 | c.919C>A p.Q307K | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV100450115, COSV58410005; called by muse, mutect2, varscan2
- ZNF479 | c.1568G>T p.C523F | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV100483004; called by muse, mutect2, varscan2
- ZNF510 | c.548T>G p.L183W | Missense Mutation (SNP) | VAF 68/282 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs922792120, COSV99793942; called by muse, mutect2, varscan2
- ZNF518B | c.2720C>A p.P907H | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV100456842; called by muse, mutect2, varscan2
- ZNF568 | c.1691G>T p.G564V | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV100451405; called by muse, varscan2
- ZNF610 | c.1388G>T p.*463Lext*6 | Nonstop Mutation (SNP) | VAF 58/190 reads (31%) | catalogued as rs779018478, COSV100016982; called by muse, mutect2, varscan2
- ZNF639 | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as COSV100418478; called by muse, mutect2, varscan2
- ZNF676 | c.1247A>T p.K416M (on ENST00000650058; = p.K384M on NM_001001411.3) | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101236316; called by muse, varscan2
- ZNF683 | c.712A>T p.M238L | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV100853736; called by muse, mutect2, varscan2
- ZNF700 | c.2144A>G p.Y715C | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV54312843; called by muse, mutect2, varscan2
- ZNF718 | c.312G>C p.E104D | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.824); catalogued as COSV101210279; called by muse, mutect2, varscan2
- ZNF718 | c.962C>T p.T321I | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.828); catalogued as rs1371162513, COSV101210281; called by muse, mutect2
- ZNF80 | c.98A>T p.D33V | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV100352131; called by muse, mutect2, varscan2
- ZNF804A | c.1090G>T p.D364Y | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as COSV100169758, COSV56443109; called by muse, mutect2, varscan2
- ZNF804B | c.839A>G p.E280G | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100305713, COSV100306754; called by muse, mutect2, varscan2
- ZNF93 | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); catalogued as rs375783215; called by muse, mutect2, varscan2
- ZNF99 | c.953G>T p.C318F | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101233928; called by muse, mutect2, varscan2
- ZZEF1 | c.1441C>A p.L481I | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101067899; called by muse, varscan2
- CACNA1D | c.2577del p.I860Sfs*18 (on ENST00000350061 / NM_001128840.3; = p.I880Sfs*18 on NM_000720.4) | Frame Shift Del (DEL) | VAF 12/104 reads (12%) | called by mutect2, pindel, varscan2
- ESRRG | c.1160C>G p.A387G | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- FAR2 | c.541del p.E182Sfs*3 | Frame Shift Del (DEL) | VAF 152/336 reads (45%) | called by mutect2, pindel, varscan2
- GSDMB | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 27/239 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGKV2-24 | c.305G>T p.R102M | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- IGKV3D-11 | c.214T>A p.S72T | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- IGKV6D-41 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
- KIFC2 | c.1417C>T p.L473F | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- MCF2 | c.1338del p.T447Hfs*20 | Frame Shift Del (DEL) | VAF 94/222 reads (42%) | called by mutect2, pindel, varscan2
- NACC2 | c.766A>T p.T256S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- OLFM4 | c.962dup p.L321Ffs*9 | Frame Shift Ins (INS) | VAF 16/114 reads (14%) | called by mutect2, pindel, varscan2
- OR11H12 | c.8C>A p.P3H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by mutect2, varscan2
- TAOK3 | c.1034del p.G345Afs*11 | Frame Shift Del (DEL) | VAF 42/137 reads (31%) | called by mutect2, pindel, varscan2
- TC2N | c.1224_1232dup p.L410_K411insNLL | In Frame Ins (INS) | VAF 40/166 reads (24%) | called by mutect2, varscan2
- TRBV27 | c.142C>A p.H48N | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- TRBV29-1 | c.198G>T p.Q66H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ADAM21 | c.1341T>C p.A447= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV99961380; called by muse, mutect2, varscan2
- ADGRL3 | c.2764C>T p.L922= (on ENST00000506720 / NM_001322402.2; = p.L854= on NM_015236.6) | Silent (SNP) | VAF 40/288 reads (14%) | catalogued as COSV72230600; called by muse, mutect2, varscan2
- ANKRD55 | c.948C>T p.L316= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV100591571, COSV61946117; called by muse, mutect2, varscan2
- ARHGAP17 | c.213G>C p.L71= | Silent (SNP) | VAF 126/400 reads (32%) | catalogued as COSV99253944; called by muse, mutect2, varscan2
- ATXN2 | c.3639G>A p.S1213= (on ENST00000550104; = p.S1053= on NM_002973.4) | Silent (SNP) | VAF 78/580 reads (13%) | catalogued as rs776360703, COSV57982539; called by muse, mutect2, varscan2
- BBS2 | c.2016C>G p.L672= | Silent (SNP) | VAF 78/570 reads (14%) | catalogued as rs768160656, COSV99802743; called by muse, mutect2, varscan2
- CACNB2 | c.453G>A p.K151= (on ENST00000324631 / NM_201596.3; = p.K96= on NM_000724.4) | Silent (SNP) | VAF 34/225 reads (15%) | catalogued as COSV99996059; called by muse, mutect2, varscan2
- CAVIN1 | c.771C>G p.L257= | Silent (SNP) | VAF 25/167 reads (15%) | catalogued as COSV100824598, COSV63812456; called by muse, mutect2, varscan2
- CD200R1L | c.684C>G p.L228= | Silent (SNP) | VAF 33/244 reads (14%) | catalogued as COSV101236628; called by muse, mutect2, varscan2
- CDC20B | c.226A>C p.R76= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as COSV57052783, COSV57054933; called by muse, mutect2
- CDH19 | c.666A>T p.V222= | Silent (SNP) | VAF 24/186 reads (13%) | catalogued as COSV100052166; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3276C>T p.V1092= | Silent (SNP) | VAF 84/239 reads (35%) | catalogued as rs750972614, COSV100575709; called by muse, mutect2, varscan2
- CECR2 | c.1248C>A p.S416= (on ENST00000342247 / NM_001290047.2; = p.S233= on NM_001290046.1) | Silent (SNP) | VAF 72/142 reads (51%) | catalogued as rs200923527, COSV52841359; called by muse, mutect2, varscan2
- CFH | c.957A>G p.R319= | Silent (SNP) | VAF 38/119 reads (32%) | catalogued as COSV100661610; called by muse, mutect2, varscan2
- CKAP2L | c.93C>T p.S31= | Silent (SNP) | VAF 105/362 reads (29%) | catalogued as COSV56696434; called by muse, mutect2, varscan2
- COG7 | c.333T>A p.I111= | Silent (SNP) | VAF 54/230 reads (23%) | catalogued as COSV100207773; called by muse, mutect2, varscan2
- COL16A1 | c.2814C>G p.L938= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV54713644, COSV99595284; called by muse, mutect2, varscan2
- CSHL1 | c.147G>T p.L49= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV51989424, COSV99368156; called by muse, mutect2, varscan2
- DCAF7 | c.1008C>T p.C336= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV100177742; called by muse, mutect2, varscan2
- DDX47 | c.528C>T p.A176= | Silent (SNP) | VAF 67/293 reads (23%) | catalogued as rs750548037, COSV61911941; called by muse, mutect2, varscan2
- DDX5 | c.1782A>G p.A594= | Silent (SNP) | VAF 95/360 reads (26%) | catalogued as rs919597544, COSV99858222; called by muse, mutect2
- DISP3 | c.3624G>T p.L1208= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99609784; called by muse, mutect2, varscan2
- DNAH8 | c.10908A>T p.T3636= | Silent (SNP) | VAF 119/367 reads (32%) | catalogued as COSV100546905; called by muse, mutect2, varscan2
- DNAJC30 | c.225C>A p.L75= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV56094826; called by muse, mutect2, varscan2
- DOCK4 | c.2781A>G p.T927= | Silent (SNP) | VAF 47/288 reads (16%) | catalogued as COSV101447955; called by muse, mutect2
- DSCAM | c.5085T>A p.A1695= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV101261370; called by muse, varscan2
- DSEL | c.552A>G p.L184= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV100026016; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2301C>A p.V767= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100668813; called by muse, mutect2
- EIF4A3 | c.1167C>G p.L389= | Silent (SNP) | VAF 26/255 reads (10%) | catalogued as COSV99484189; called by muse, mutect2, varscan2
- EMSY | c.2961C>G p.L987= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as COSV58265238; called by muse, mutect2, varscan2
- EXT1 | c.1980G>C p.L660= | Silent (SNP) | VAF 172/529 reads (33%) | catalogued as COSV100984122; called by muse, mutect2, varscan2
- FAM24B | c.30G>T p.A10= | Silent (SNP) | VAF 34/212 reads (16%) | catalogued as rs558510109, COSV100158956, COSV59025926; called by mutect2, varscan2
- FAT3 | c.10383G>T p.V3461= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as COSV99970136; called by muse, mutect2, varscan2
- FLII | c.1290G>A p.L430= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV100493796; called by muse, mutect2, varscan2
- FRMD4A | c.522G>C p.L174= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV52730923, COSV99198645; called by muse, mutect2, varscan2
- FZD3 | c.1872T>C p.S624= | Silent (SNP) | VAF 33/214 reads (15%) | catalogued as rs764506016, COSV99528344; called by muse, mutect2, varscan2
- GIMAP8 | c.729G>A p.P243= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs762955793, COSV56233382; called by muse, mutect2, varscan2
- HDC | c.957G>A p.K319= | Silent (SNP) | VAF 54/140 reads (39%) | catalogued as COSV99984278; called by muse, mutect2, varscan2
- HEATR6 | c.3459C>A p.A1153= | Silent (SNP) | VAF 59/263 reads (22%) | catalogued as COSV99482574; called by muse, varscan2
- HRC | c.1194C>A p.G398= | Silent (SNP) | VAF 23/129 reads (18%) | catalogued as COSV99418262; called by muse, mutect2, varscan2
- IL2RA | c.534C>A p.T178= | Silent (SNP) | VAF 23/121 reads (19%) | catalogued as COSV99906872; called by muse, mutect2, varscan2
- IQGAP2 | c.2904C>A p.V968= | Silent (SNP) | VAF 26/182 reads (14%) | catalogued as COSV99167560, COSV99167909; called by muse, mutect2, varscan2
- JRK | c.180G>T p.A60= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs782439628, COSV70629551, COSV70630757; called by muse, mutect2, varscan2
- KCNF1 | c.558G>T p.V186= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99705856; called by muse, varscan2
- KIAA1614 | c.3474T>A p.G1158= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100799874; called by muse, varscan2
- KIF5A | c.741C>T p.A247= | Silent (SNP) | VAF 22/128 reads (17%) | catalogued as rs769133499, COSV54056036; called by muse, varscan2
- KLHL4 | c.1254C>T p.S418= | Silent (SNP) | VAF 90/161 reads (56%) | catalogued as COSV100910115; called by muse, mutect2, varscan2
- KRTAP5-5 | c.690C>A p.P230= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs183750160; called by muse, mutect2, varscan2
- LAMB2 | c.5280G>A p.E1760= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as rs970982118, COSV100026438; called by muse, mutect2, varscan2
- LSM14B | c.780C>G p.A260= | Silent (SNP) | VAF 83/373 reads (22%) | catalogued as COSV99444691; called by muse, mutect2, varscan2
- M1AP | c.423G>T p.L141= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as COSV99304463; called by muse, mutect2, varscan2
- MAGEB6B | c.987G>A p.R329= | Silent (SNP) | VAF 81/185 reads (44%) | catalogued as rs779434847; called by muse, mutect2, varscan2
- MAP2 | c.5340A>G p.T1780= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as COSV99561473; called by muse, mutect2
- MCF2L | c.2928C>T p.P976= (on ENST00000375608; = p.P944= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as COSV99996110; called by muse, mutect2
- MOGAT2 | c.831C>G p.R277= | Silent (SNP) | VAF 14/152 reads (9%) | catalogued as COSV52219091, COSV99549698; called by muse, mutect2
- MUC16 | c.39297G>A p.L13099= | Silent (SNP) | VAF 14/136 reads (10%) | catalogued as COSV101110055; called by muse, varscan2
- MYH4 | c.1332C>T p.T444= | Silent (SNP) | VAF 60/221 reads (27%) | catalogued as COSV55118838; called by muse, mutect2, varscan2
- NAV3 | c.1200G>T p.P400= | Silent (SNP) | VAF 19/109 reads (17%) | catalogued as COSV57077489, COSV99894680; called by muse, mutect2, varscan2
- NAV3 | c.2235C>A p.G745= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV99894684; called by muse, mutect2, varscan2
- NCKAP1L | c.816C>T p.N272= | Silent (SNP) | VAF 49/263 reads (19%) | catalogued as COSV99515574; called by muse, mutect2, varscan2
- NLRP4 | c.549G>T p.L183= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100016988; called by muse, mutect2, varscan2
- OCA2 | c.1287C>G p.L429= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV100668366, COSV100668536, COSV62338686; called by muse, mutect2, varscan2
- OGDHL | c.360G>A p.L120= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100934492; called by muse, mutect2, varscan2
- OR10K1 | c.30A>G p.R10= | Silent (SNP) | VAF 26/146 reads (18%) | catalogued as COSV99193887; called by muse, varscan2
- OR10S1 | c.495A>T p.I165= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as rs150736223; called by muse, mutect2, varscan2
- OR8K3 | c.477C>A p.V159= | Silent (SNP) | VAF 48/198 reads (24%) | catalogued as COSV100449881; called by muse, varscan2
- PCDHA3 | c.291G>C p.G97= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV100974120; called by muse, mutect2, varscan2
- PCDHB2 | c.648G>T p.A216= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs782259874, COSV99523506; called by muse, mutect2, varscan2
- PCDHGB3 | c.199C>A p.R67= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs373364003; called by muse, mutect2, varscan2
- PDGFRA | c.2265C>A p.S755= | Silent (SNP) | VAF 78/251 reads (31%) | catalogued as COSV99957457; called by muse, mutect2, varscan2
- PER3 | c.543G>T p.A181= | Silent (SNP) | VAF 31/161 reads (19%) | catalogued as COSV100728457, COSV62704271; called by muse, mutect2, varscan2
- PHGDH | c.489G>T p.R163= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as COSV101025205; called by muse, mutect2
- PORCN | c.417C>T p.F139= | Silent (SNP) | VAF 32/56 reads (57%) | catalogued as rs1556974102, COSV100400531; called by muse, mutect2, varscan2
- PTGS1 | c.1707C>A p.L569= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV99793482; called by muse, mutect2, varscan2
- PTPRB | c.855C>T p.V285= | Silent (SNP) | VAF 47/309 reads (15%) | catalogued as rs767836009, COSV54255516; called by muse, mutect2, varscan2
- PYGB | c.2127C>T p.L709= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs1180233701, COSV99405410; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1665C>T p.H555= | Silent (SNP) | VAF 151/490 reads (31%) | catalogued as COSV62787019; called by muse, mutect2, varscan2
- RALYL | c.132G>A p.K44= | Silent (SNP) | VAF 34/158 reads (22%) | catalogued as rs781174611, COSV101569416; called by muse, mutect2, varscan2
- RELN | c.10189C>A p.R3397= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as COSV100634658, COSV58987283; called by muse, mutect2, varscan2
- RELN | c.7824G>T p.L2608= | Silent (SNP) | VAF 60/267 reads (22%) | catalogued as COSV100634660; called by muse, mutect2, varscan2
- RHEB | c.186C>T p.A62= | Silent (SNP) | VAF 44/305 reads (14%) | catalogued as rs140516831; called by muse, mutect2, varscan2
- SATB2 | c.858G>A p.V286= | Silent (SNP) | VAF 84/486 reads (17%) | catalogued as COSV99612363; called by muse, mutect2, varscan2
- SCFD1 | c.843G>T p.V281= | Silent (SNP) | VAF 59/306 reads (19%) | catalogued as COSV100356524; called by muse, mutect2, varscan2
- SIRPB1 | c.477C>T p.A159= | Silent (SNP) | VAF 46/183 reads (25%) | catalogued as COSV99498543; called by muse, mutect2, varscan2
- SLC35A2 | c.360C>T p.L120= | Silent (SNP) | VAF 63/144 reads (44%) | catalogued as COSV99504496; called by muse, mutect2, varscan2
- SLC35E4 | c.888C>T p.L296= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV55898858; called by muse, mutect2, varscan2
- SPTBN5 | c.6894C>A p.R2298= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs546749760, COSV100310921, COSV58026656; called by muse, varscan2
- SSU72P8 | c.486G>T p.L162= | Silent (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- STAB1 | c.3630C>T p.S1210= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV58743773; called by muse, mutect2, varscan2
- TAF1L | c.1953T>C p.G651= | Silent (SNP) | VAF 113/544 reads (21%) | catalogued as COSV99645293; called by muse, varscan2
- TEK | c.1386C>A p.V462= | Silent (SNP) | VAF 122/330 reads (37%) | catalogued as COSV101193543; called by muse, mutect2, varscan2
- TEX101 | c.153G>A p.V51= (on ENST00000598265 / NM_001130011.3; = p.V69= on NM_031451.4) | Silent (SNP) | VAF 26/206 reads (13%) | catalogued as COSV99494946; called by muse, mutect2, varscan2
- THEMIS | c.1146C>A p.S382= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as COSV64072401, COSV64072792; called by muse, mutect2, varscan2
- TLN2 | c.6396T>A p.T2132= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100169871; called by muse, mutect2, varscan2
- TRPM3 | c.1239G>T p.L413= (on ENST00000357533 / NM_001366142.2; = p.L258= on NM_020952.6) | Silent (SNP) | VAF 76/356 reads (21%) | catalogued as COSV100678474; called by muse, varscan2
- UBAC2 | c.576C>T p.C192= (on ENST00000403766 / NM_001144072.2; = p.C157= on NM_177967.4) | Silent (SNP) | VAF 21/144 reads (15%) | catalogued as COSV100854378; called by muse, mutect2, varscan2
- UHRF1BP1 | c.2170C>T p.L724= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as COSV99512384; called by muse, mutect2, varscan2
- ZMIZ1 | c.2331G>T p.G777= | Silent (SNP) | VAF 62/184 reads (34%) | catalogued as COSV100566482; called by muse, mutect2, varscan2
- AL590867.2 | n.307G>A | RNA (SNP) | VAF 40/205 reads (20%) | catalogued as rs755611860; called by muse, mutect2, varscan2
- GABPB1 | c.1035+32G>T | Intron (SNP) | VAF 149/425 reads (35%) | catalogued as rs145682817; called by muse, mutect2, varscan2
- GLRXP3 | n.270dup | RNA (INS) | VAF 17/85 reads (20%) | called by mutect2, pindel, varscan2
- MICAL3 | c.-75+43398G>T | Intron (SNP) | VAF 20/45 reads (44%) | catalogued as rs766122922, COSV99262707; called by muse, mutect2, varscan2
- MIR770 | n.35C>A | RNA (SNP) | VAF 8/28 reads (29%) | called by mutect2, varscan2
- NCOA1 | c.4156-97A>G | Intron (SNP) | VAF 46/164 reads (28%) | catalogued as COSV99946884; called by muse, varscan2
- NTRK3 | c.1586-38671G>T | Intron (SNP) | VAF 118/312 reads (38%) | catalogued as COSV100447858; called by muse, mutect2, varscan2
- OR2W5 | n.1043C>A | RNA (SNP) | VAF 23/61 reads (38%) | called by muse, mutect2, varscan2
- PAX3 | c.586+438G>T | Intron (SNP) | VAF 13/109 reads (12%) | catalogued as rs750122824, COSV51338832, COSV99286766; called by muse, mutect2, varscan2
- RMDN2 | c.453-22053A>T | Intron (SNP) | VAF 73/231 reads (32%) | catalogued as COSV99308144; called by muse, varscan2
- SCN5A | c.612-158C>A | Intron (SNP) | VAF 46/186 reads (25%) | catalogued as COSV100350171; called by muse, varscan2
- SLC25A3 | c.282+235dup | Intron (INS) | VAF 302/818 reads (37%) | called by mutect2, pindel, varscan2
- SYTL2 | c.1459+2706G>A | Intron (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100314801; called by muse, mutect2
- XIRP2 | c.*1160A>T | 3'UTR (SNP) | VAF 13/87 reads (15%) | catalogued as rs759323118, COSV99746577; called by muse, mutect2, varscan2
